FM case AD1756 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/878b133a-7f55-4bc4-9314-221e4a61b9cd

Female, 60.5 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the lung; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
